TCGA case TCGA-CR-7401 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue; Tissue source site: Vanderbilt University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e2e64c5d-44ba-42f0-ab9d-ec16b21d2545

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C02.9; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 64.1 years (23,420 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage I; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,077 days (2.9 years).
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 0; Lymph nodes tested: 27; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection method: Modified Radical Neck Dissection; Lymph node dissection site: Neck, Right.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 1,077 days (2.9 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 66; Tobacco smoking onset year: 1963; Tobacco smoking quit year: 2007.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CR-7401-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.1; Intermediate dimension: 0; Shortest dimension: 0.
  Slide TCGA-CR-7401-01A-01-TS1: Section location: Top; Percent tumor cells: 78; Percent tumor nuclei: 75; Percent normal cells: 12; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 10.
- Sample TCGA-CR-7401-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Anatomic organ subdivision: Oral Tongue; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Lymphovascular invasion: No; Tobacco smoking history indicator: 4; Alcohol history documented: Yes.
- Follow-up form: New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,077 days; disease-specific survival: no event (censored), 1,077 days; disease-free interval: no event (censored), 1,077 days; progression-free interval: no event (censored), 1,077 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CR-7401-01A-11D-2010-01): tumor purity 0.33, ploidy 2.03, whole-genome doublings 0.
